Somatic mutation profile of tumor specimen MP2PRT-PAUXGW-TMP1-A (aliquot MP2PRT-PAUXGW-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUXGW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,088 days).
Specimen MP2PRT-PAUXGW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d13532b5-37ca-426d-87be-b48f3d9ba665.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUXGW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUXGW-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/618128f5-1705-4200-9cec-6adcedae174d

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 91/375 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKRD30B | c.2972C>T p.A991V | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs758125524, COSV57703440; called by muse, mutect2, varscan2
- ARPP21 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 94/275 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as rs199754646, COSV51799772; called by muse, varscan2
- CCKAR | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 163/551 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as rs756393377; called by muse, mutect2, varscan2
- ABCB11 | c.3779C>T p.A1260V | Missense Mutation (SNP) | VAF 126/288 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- CDK11B | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 69/239 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADAM32 | c.732G>A p.K244= | Silent (SNP) | VAF 92/388 reads (24%) | catalogued as COSV101165540; called by muse, mutect2, varscan2
- PBRM1 | c.690C>G p.L230= | Silent (SNP) | VAF 62/188 reads (33%) | called by muse, mutect2, varscan2
